Somatic mutation profile of tumor specimen TARGET-40-PAPVYW-01A (aliquot TARGET-40-PAPVYW-01A-01D) from TARGET case TARGET-40-PAPVYW, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 7.7 years (2,803 days).
Specimen TARGET-40-PAPVYW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e60e4a1-7622-4ee7-99e8-03962ed42e77.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PAPVYW-10A (Blood Derived Normal), aliquot TARGET-40-PAPVYW-10A-01Y; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a469b91-e045-4b46-b54f-d86041f775b7

The open-access MAF lists 31 somatic variants for this specimen: 25 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Nonsense Mutation 3, Silent 3, Intron 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 12/42 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- CD6 | c.118G>T p.G40W | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57842607; called by muse, mutect2
- GRSF1 | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as rs774281565; called by muse, mutect2, varscan2
- NETO2 | c.409A>T p.M137L | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs1023173880; called by muse, mutect2, varscan2
- NOTCH3 | c.1238G>A p.G413D | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54636526; called by muse, mutect2, varscan2
- PCDH11X | c.2959G>T p.D987Y | Missense Mutation (SNP) | VAF 77/106 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53460596; called by muse, mutect2, varscan2
- SEC24D | c.794C>G p.P265R | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54885758; called by muse, mutect2, varscan2
- SYNE1 | c.13360G>A p.E4454K (on ENST00000367255 / NM_182961.4; = p.E4383K on NM_033071.3) | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs192299401, COSV55109748; called by muse, mutect2, varscan2
- THSD7A | c.2059C>G p.R687G | Missense Mutation (SNP) | VAF 51/251 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70273186; called by muse, mutect2, varscan2
- ADAM30 | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- CEP152 | c.4922C>G p.S1641* (on ENST00000380950 / NM_001194998.2; = p.S1585* on NM_014985.4) | Nonsense Mutation (SNP) | VAF 39/180 reads (22%) | called by muse, mutect2, varscan2
- CEP152 | c.4657C>T p.Q1553* (on ENST00000380950 / NM_001194998.2; = p.Q1497* on NM_014985.4) | Nonsense Mutation (SNP) | VAF 18/97 reads (19%) | called by muse, mutect2, varscan2
- DNAH9 | c.10712C>A p.T3571N | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- EML3 | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- JAK2 | c.1125A>C p.L375F | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- KMT2D | c.10705G>T p.E3569* | Nonsense Mutation (SNP) | VAF 146/223 reads (65%) | called by muse, mutect2, varscan2
- PLEKHG4 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.243); called by muse, mutect2
- RBBP8 | c.1426G>T p.D476Y | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); called by mutect2, varscan2
- RMDN1 | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2
- SMPDL3B | c.843C>A p.D281E | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM71 | c.212G>A p.G71D | Missense Mutation (SNP) | VAF 122/173 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPM3 | c.3548T>G p.L1183R (on ENST00000357533 / NM_001366142.2; = p.L1038R on NM_020952.6) | Missense Mutation (SNP) | VAF 105/241 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- VEGFC | c.910T>A p.C304S | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- ZNF560 | c.1303G>T p.D435Y | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- ZSWIM8 | c.2862G>T p.E954D (on ENST00000605216 / NM_001242487.2; = p.E959D on NM_015037.3) | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MAN2C1 | c.3018A>C p.P1006= | Silent (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- PIK3R2 | c.846G>A p.L282= | Silent (SNP) | VAF 44/87 reads (51%) | called by muse, mutect2, varscan2
- STRN3 | c.996T>C p.D332= | Silent (SNP) | VAF 16/78 reads (21%) | called by muse, mutect2, varscan2
- CNTN6 | c.761+61del | Intron (DEL) | VAF 5/19 reads (26%) | called by mutect2, varscan2
- GUSBP12 | n.646C>T | RNA (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2
- USP17L2 | c.-91T>C | 5'UTR (SNP) | VAF 7/72 reads (10%) | catalogued as rs748652021, COSV61556922; called by mutect2, varscan2
